Gene-level copy-number profile of tumor specimen C3L-03372-04 from CPTAC case C3L-03372, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.6 years (11,529 days).
Specimen C3L-03372-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e450ba91-02c3-4c54-bf1e-32c580ecb970.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03372-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,867 have no estimate.
https://portal.gdc.cancer.gov/files/d21edb20-e4a4-4e12-bb81-ead692d90e7d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 9,620; copy number 2: 45,519; copy number 3: 2,476; copy number 4: 615; copy number 5: 407; copy number 13: 4.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr9:12,134–1,333,953, 32 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr9:20,331,446–23,849,914, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 411 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:6,346,843–6,866,632, 45 genes, copy number 5: SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3, USP5.
- chr12:121,237,675–133,238,549, 359 genes, copy number 5 (broad region; genes not listed).
- chr22:18,527,157–18,530,573, 2 genes, copy number 5: AC023490.3, TMEM191B.
- chr22:18,605,355–18,615,900, 4 genes, copy number 13: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.
- chr22:18,636,445–18,638,405, 1 gene, copy number 5: CA15P2.

Autosomal genes at a single copy (total copy number 1): 6,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
